CCDI case PBBLSE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/99c823ed-12e3-4475-9797-51e79f7c2aff

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 8.0 years (2,919 days).

Biospecimens (3 samples)
- Sample 0DCM10: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCM18: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCM1L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
